Somatic mutation profile of tumor specimen TCGA-BA-A6DI-01A (aliquot TCGA-BA-A6DI-01A-11D-A30E-08) from TCGA case TCGA-BA-A6DI, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 62.6 years (22,857 days).
Specimen TCGA-BA-A6DI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7289824b-4397-472f-a68d-077ef18de9d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-A6DI-10A (Blood Derived Normal), aliquot TCGA-BA-A6DI-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86f07d76-05bb-4bfa-bb8d-1d00f8ac5f9a

The open-access MAF lists 102 somatic variants for this specimen: 82 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 19, Nonsense Mutation 7, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 18/100 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSBG1 | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.892); catalogued as rs370057969; called by muse, mutect2, varscan2
- APOB | c.12499C>T p.L4167F | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV99267357; called by muse, mutect2
- ARMC6 | c.187G>A p.E63K (on ENST00000392336; = p.E38K on NM_033415.4) | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV99523142; called by muse, mutect2
- ATP8B2 | c.3320C>T p.T1107I (on ENST00000672630; = p.T1074I on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as rs772244439, COSV100874546; called by muse, mutect2, varscan2
- BCKDHB | c.769A>G p.N257D | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV100243962; called by muse, mutect2, varscan2
- CATSPERD | c.987+1G>A p.X329_splice | Splice Site (SNP) | VAF 7/55 reads (13%) | catalogued as rs775477485, COSV100486945; called by muse, mutect2, varscan2
- CCDC15 | c.1521G>T p.Q507H | Missense Mutation (SNP) | VAF 64/370 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs183310714, COSV100777044; called by muse, varscan2
- CCT6A | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as COSV51906499; called by muse, mutect2, varscan2
- CDH23 | c.2242G>T p.A748S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752103709, COSV54952692, COSV99818631, COSV99823209; called by muse, mutect2, varscan2
- CEP63 | c.826C>T p.L276F | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs763815982, COSV59680446; called by muse, mutect2, varscan2
- CHMP2B | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs1185719298, COSV99773638; called by muse, mutect2, varscan2
- CNDP1 | c.494A>G p.D165G | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771780063, COSV100722502; called by muse, varscan2
- CUBN | c.2172G>T p.L724F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.076); catalogued as COSV100913371; called by muse, mutect2, varscan2
- CXCR5 | c.914C>T p.T305I | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.069); catalogued as COSV99419975; called by muse, mutect2, varscan2
- DACT1 | c.1490C>A p.P497Q | Missense Mutation (SNP) | VAF 64/259 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100242055; called by muse, mutect2, varscan2
- DLG1 | c.1482C>G p.I494M | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1163879679, COSV100015855, COSV58382531; called by muse, mutect2, varscan2
- DMGDH | c.2399C>T p.T800M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs151220884; called by muse, mutect2, varscan2
- DRAM2 | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1170458615, COSV99713459; called by muse, mutect2, varscan2
- EIF2S3 | c.1348C>T p.H450Y | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99451091; called by muse, mutect2, varscan2
- FAT1 | c.5383C>T p.R1795* | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as rs769432838, COSV71674862; called by muse, mutect2, varscan2
- FAT3 | c.5632G>C p.D1878H | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53116186, COSV99969725; called by muse, mutect2
- FGGY | c.1075T>A p.C359S | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99054543; called by muse, mutect2, varscan2
- FSHR | c.146T>A p.I49N | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV58634881; called by muse, mutect2, varscan2
- GNAZ | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 70/435 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as COSV99321119; called by muse, mutect2, varscan2
- GYS2 | c.671T>G p.L224R | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99680129; called by muse, mutect2, varscan2
- HELB | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 36/188 reads (19%) | catalogued as COSV99922142; called by muse, mutect2, varscan2
- HEXA | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 47/309 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99173826; called by muse, mutect2, varscan2
- HOXC4 | c.626T>A p.M209K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100324355; called by muse, mutect2, varscan2
- HSCB | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV99319690; called by muse, mutect2, varscan2
- HTT | c.4663A>G p.T1555A | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs998505909, COSV100751140; called by muse, mutect2, varscan2
- IKBKB | c.1738G>T p.D580Y | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV100645804; called by muse, mutect2, varscan2
- IMMP1L | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs1198570161, COSV99541257; called by muse, mutect2, varscan2
- INPP4A | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.559); catalogued as rs1320693278, COSV50785335; called by muse, mutect2, varscan2
- IQCJ | c.328A>T p.I110F | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV101188750; called by muse, mutect2, varscan2
- ITGB4 | c.21C>G p.S7R | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.08); catalogued as COSV99564604; called by muse, mutect2, varscan2
- KCNT2 | c.1615G>T p.G539C | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99656070; called by muse, mutect2, varscan2
- KDM5C | c.632G>C p.R211P | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100855492, COSV62890801; called by muse, mutect2, varscan2
- KMT2D | c.4468G>T p.E1490* | Nonsense Mutation (SNP) | VAF 24/140 reads (17%) | catalogued as COSV99985111; called by muse, mutect2, varscan2
- LAMA3 | c.1546G>C p.E516Q | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.049); catalogued as COSV100557517; called by muse, mutect2, varscan2
- LILRB2 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs145209585; called by muse, mutect2
- LIME1 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs774768440, COSV100203262; called by muse, mutect2, varscan2
- LRFN5 | c.1297C>A p.L433I | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99985070; called by muse, mutect2, varscan2
- METTL22 | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 56/409 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as COSV99371834; called by muse, mutect2, varscan2
- MROH2B | c.2167C>G p.Q723E | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs766752694, COSV68186705, COSV68187077; called by muse, mutect2, varscan2
- MTREX | c.1670A>G p.D557G | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV100044428; called by muse, mutect2, varscan2
- NCF2 | c.1385T>C p.V462A | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV100838935; called by muse, mutect2, varscan2
- NCOR2 | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as rs1488718449, COSV100657760; called by muse, mutect2, varscan2
- OR4C6 | c.714C>A p.C238* | Nonsense Mutation (SNP) | VAF 23/185 reads (12%) | catalogued as COSV100051803; called by muse, mutect2, varscan2
- OR5D16 | c.308T>G p.F103C | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV101004111; called by muse, varscan2
- OR5D16 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as rs562661348, COSV65722453; called by muse, varscan2
- PIP5K1B | c.412A>G p.K138E | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99599566; called by muse, mutect2, varscan2
- PNMA2 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV101580643; called by muse, mutect2, varscan2
- PRB4 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 79/369 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as rs754614621, COSV99686771; called by muse, mutect2, varscan2
- PRDM9 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 47/270 reads (17%) | catalogued as COSV57007260, COSV99691034; called by muse, mutect2, varscan2
- PTK2 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.094); catalogued as COSV61792350; called by muse, mutect2, varscan2
- REST | c.1348C>T p.Q450* | Nonsense Mutation (SNP) | VAF 23/83 reads (28%) | catalogued as COSV100471268; called by muse, mutect2, varscan2
- RETREG2 | c.601G>T p.G201* | Nonsense Mutation (SNP) | VAF 36/278 reads (13%) | catalogued as COSV99811674; called by muse, mutect2, varscan2
- RIPOR3 | c.2437C>A p.Q813K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.121); catalogued as COSV99247009; called by muse, mutect2, varscan2
- SDK2 | c.1445G>A p.G482E | Missense Mutation (SNP) | VAF 39/343 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV101168351; called by muse, mutect2, varscan2
- SHROOM3 | c.5772C>A p.F1924L | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV56036933, COSV99935104; called by muse, mutect2, varscan2
- SLC5A8 | c.745G>C p.G249R | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101610595; called by muse, mutect2
- SLC9A3 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99376473, COSV99376554; called by muse, mutect2
- STXBP5L | c.1981G>A p.G661R | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV99875907; called by muse, mutect2, varscan2
- TBC1D32 | c.3458C>A p.P1153Q | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99251017; called by muse, mutect2
- TNC | c.1336C>T p.R446W | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771736820, COSV60790872; called by muse, mutect2
- TPH2 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV61590861, COSV61591960; called by muse, varscan2
- TRIM6-TRIM34 | c.2419G>A p.G807S | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100709168; called by muse, mutect2, varscan2
- TRPS1 | c.2821G>C p.G941R (on ENST00000220888 / NM_001330599.2; = p.G954R on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55254581; called by muse, mutect2, varscan2
- TSPYL2 | c.1246A>T p.R416W | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV100966355; called by muse, mutect2, varscan2
- UBR5 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.901); catalogued as COSV99642034; called by muse, mutect2
- USP34 | c.8611C>G p.Q2871E | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV101277169; called by muse, mutect2, varscan2
- USP36 | c.1534G>T p.G512W | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.195); catalogued as rs1452062203, COSV100361752; called by muse, mutect2, varscan2
- WFIKKN2 | c.1604G>A p.G535D | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100260062; called by muse, mutect2, varscan2
- XIRP1 | c.4793G>T p.G1598V | Missense Mutation (SNP) | VAF 46/258 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV100453887; called by muse, mutect2, varscan2
- XIRP2 | c.9942A>T p.R3314S (on ENST00000628543; = p.R3489S on NM_152381.6) | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV99746407; called by muse, mutect2
- ZNF80 | c.645G>T p.K215N | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100352127; called by muse, mutect2
- ZNF93 | c.1194A>T p.K398N | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100652385; called by muse, mutect2, varscan2
- EFCAB13 | c.2662G>A p.E888K | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); called by muse, mutect2
- LPCAT3 | c.1085dup p.Q363Sfs*87 | Frame Shift Ins (INS) | VAF 24/223 reads (11%) | called by mutect2, varscan2
- PLXND1 | c.2247_2249del p.Q750del | In Frame Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- ZNF683 | c.1506del p.A504Qfs*4 (on ENST00000403843; = p.A484Qfs*4 on NM_173574.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 69/245 reads (28%) | called by mutect2, pindel, varscan2
- DEFB119 | c.174G>A p.Q58= | Silent (SNP) | VAF 26/162 reads (16%) | catalogued as COSV99489309; called by muse, mutect2, varscan2
- DMBT1 | c.1590G>T p.V530= | Silent (SNP) | VAF 96/792 reads (12%) | catalogued as COSV57540303; called by muse, mutect2, varscan2
- FAAP20 | c.138G>T p.T46= | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as COSV101052052; called by muse, mutect2, varscan2
- MAP3K19 | c.2049G>A p.T683= | Silent (SNP) | VAF 23/225 reads (10%) | catalogued as rs772463656, COSV100208716; called by muse, mutect2, varscan2
- NAV2 | c.6225A>T p.L2075= (on ENST00000396087 / NM_001244963.2; = p.L2016= on NM_145117.5) | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as COSV100217539; called by muse, mutect2, varscan2
- NFE2 | c.561C>T p.N187= | Silent (SNP) | VAF 22/147 reads (15%) | catalogued as COSV100380838; called by muse, mutect2, varscan2
- OR8A1 | c.360C>T p.Y120= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as rs760259966, COSV52508153; called by muse, mutect2, varscan2
- PLCD4 | c.2061A>G p.L687= | Silent (SNP) | VAF 43/254 reads (17%) | catalogued as rs761326410, COSV101346947; called by muse, mutect2, varscan2
- PRSS53 | c.216C>T p.V72= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99762584; called by muse, mutect2, varscan2
- RELN | c.531G>A p.L177= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as COSV100634579; called by muse, mutect2, varscan2
- RP1 | c.2958A>G p.L986= | Silent (SNP) | VAF 67/274 reads (24%) | catalogued as rs1209450837, COSV99608538; called by muse, mutect2, varscan2
- RXFP4 | c.504G>A p.A168= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as rs151259651; called by muse, mutect2, varscan2
- SH3BP2 | c.768G>A p.R256= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV100696997; called by muse, mutect2
- SHLD2 | c.1759T>C p.L587= | Silent (SNP) | VAF 31/126 reads (25%) | catalogued as COSV100079434; called by muse, mutect2, varscan2
- SOS1 | c.2403A>G p.P801= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV101217213; called by muse, mutect2
- TAP2 | c.1413A>G p.Q471= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs760423636, COSV100886941; called by muse, mutect2, varscan2
- TIMD4 | c.18C>T p.L6= | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as COSV50856957, COSV99192847; called by muse, mutect2, varscan2
- TRAPPC9 | c.3354C>A p.I1118= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV101228398; called by muse, mutect2, varscan2
- ZNF569 | c.1983C>T p.P661= | Silent (SNP) | VAF 12/174 reads (7%) | catalogued as COSV100386601, COSV57597103; called by muse, mutect2
- SNORD114-22 | n.34C>T | RNA (SNP) | VAF 53/200 reads (27%) | called by muse, mutect2, varscan2
